Somatic mutation profile of tumor specimen TARGET-10-PAREHN-09A (aliquot TARGET-10-PAREHN-09A-01D) from TARGET case TARGET-10-PAREHN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.5 years (5,674 days).
Specimen TARGET-10-PAREHN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da66a048-3d15-4a3d-8a6f-ff57c322db9f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAREHN-10A (Blood Derived Normal), aliquot TARGET-10-PAREHN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39d9666a-9ccf-49b7-a585-44ca89611f43

The open-access MAF lists 22 somatic variants for this specimen: 14 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 6, Frame Shift Ins 3, 3'Flank 1, Splice Site 1, Intron 1, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.2047A>G p.R683G | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519721, COSV67572554, COSV67587550; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- IKZF1 | c.151delinsCC p.R51Pfs*6 | Frame Shift Ins (INS) | VAF 17/73 reads (23%) | catalogued as COSV58790463; called by mutect2*, pindel, varscan2*
- MALRD1 | c.4242C>A p.N1414K | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as rs373335851; called by muse, mutect2, varscan2
- MORC4 | c.2054_2056del p.E685del | In Frame Del (DEL) | VAF 15/57 reads (26%) | catalogued as rs1399025642; called by pindel, varscan2
- NIM1K | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as rs1318206375, COSV58139059; called by muse, mutect2, varscan2
- PAX5 | c.780+2T>C p.X260_splice | Splice Site (SNP) | VAF 15/53 reads (28%) | catalogued as COSV63909736; called by muse, mutect2, varscan2
- PAX5 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as CM1514451, COSV63906029; called by muse, mutect2, varscan2
- SYNE1 | c.10709G>A p.R3570Q (on ENST00000367255 / NM_182961.4; = p.R3577Q on NM_033071.3) | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751191478; called by muse, mutect2, varscan2
- CNTRL | c.4574T>G p.I1525S | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- H4C7 | c.280C>G p.Q94E | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT deleterious (0); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- IFI16 | c.1189_1190insCCTA p.N397Tfs*2 | Frame Shift Ins (INS) | VAF 33/80 reads (41%) | called by mutect2, pindel, varscan2
- IKZF1 | c.150dup p.R51Qfs*6 | Frame Shift Ins (INS) | VAF 12/58 reads (21%) | called by mutect2, varscan2
- TSPYL5 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- USP9X | c.5816_5817insGAGGCCCCACC p.Y1939* | Nonsense Mutation (INS) | VAF 33/68 reads (49%) | called by mutect2, pindel, varscan2
- CEP95 | c.1521T>C p.H507= | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as rs1353494003; called by muse, mutect2, varscan2
- CYC1 | c.669C>T p.T223= | Silent (SNP) | VAF 51/98 reads (52%) | catalogued as rs143508925; called by muse, mutect2, varscan2
- DSG1 | c.1488G>A p.P496= | Silent (SNP) | VAF 55/117 reads (47%) | catalogued as rs146820029; called by muse, mutect2, varscan2
- MATN1 | c.180G>T p.V60= | Silent (SNP) | VAF 37/93 reads (40%) | called by muse, mutect2, varscan2
- NEK8 | c.135G>T p.R45= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV99261397; called by muse, mutect2, varscan2
- SALL1 | c.219C>T p.I73= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs774483464, COSV51754062; called by muse, mutect2, varscan2
- SLAMF8 | chr1:159840975 G>T | 3'Flank (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- SMAD3 | c.1010-456G>A | Intron (SNP) | VAF 12/27 reads (44%) | called by muse, mutect2, varscan2
